Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3841, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3841-01A (Primary Tumor).

Diagnosis:

This material shows in I) parts of an invasive adenocarcinoma of the colon G2 with penetration of all parietal layers (pT3, L1, V1) and with free lymph nodes, in II) an additional adenocarcinoma, of moderate differentiation G2, with infiltration of the muscularis (pT2, L1, V1), as well as a tubular adenoma and a lymph node metastasis, thus corresponding to N1 (1 of 16).

Tumor classification:

- I ICDO-DA M-8140/3, G2, pT3, L1, V1, pN0 (0 of 24)
- II ICDO-DA M-8140/3, G2, pT2, L1, V1, pN1 (1 of 16)

Source: NCI Genomic Data Commons file de1fb4f5-3cf1-4aef-95f5-f96a86ce0b71 (TCGA-AA-3841.A7348FAF-DF79-4765-8910-B183A408E905.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).